Somatic mutation profile of tumor specimen TCGA-A4-8515-01A (aliquot TCGA-A4-8515-01A-11D-2396-08) from TCGA case TCGA-A4-8515, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 47.5 years (17,345 days).
Specimen TCGA-A4-8515-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70025b3e-b401-47d7-b947-732809aa8cad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-8515-10A (Blood Derived Normal), aliquot TCGA-A4-8515-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8271cc3-f963-4dc2-998b-4cb3e8aa2541

The open-access MAF lists 57 somatic variants for this specimen: 48 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 32, Silent 9, Frame Shift Del 7, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 1, Splice Region 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.531G>T p.K177N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV65311800; called by muse, mutect2, varscan2
- ABCC4 | c.530A>C p.K177T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV65311810; called by muse, mutect2, varscan2
- ACSM1 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV54634903; called by muse, mutect2, varscan2
- ALOX15B | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1359482693, COSV66479327; called by muse, mutect2, varscan2
- ARID1A | c.6806C>A p.S2269* | Nonsense Mutation (SNP) | VAF 46/116 reads (40%) | catalogued as COSV100252068, COSV61371645, COSV61375637; called by muse, mutect2, varscan2
- ARRDC1 | c.478C>A p.L160M | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58373892; called by muse, mutect2, varscan2
- BTG1 | c.433A>G p.S145G | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV55458661; called by muse, mutect2, varscan2
- C7orf26 | c.589A>T p.I197F | Missense Mutation (SNP) | VAF 113/199 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV60418428; called by muse, mutect2, varscan2
- CPNE1 | c.1128C>A p.Y376* (on ENST00000352393; = p.Y381* on NM_003915.5) | Nonsense Mutation (SNP) | VAF 46/100 reads (46%) | catalogued as COSV58290841; called by muse, mutect2, varscan2
- DSC2 | c.1304T>G p.I435S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51863713; called by muse, mutect2, varscan2
- EPB41L3 | c.2270A>G p.K757R | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59450494; called by muse, mutect2, varscan2
- FNBP4 | c.2381C>A p.T794K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV55447910; called by muse, mutect2
- GAPVD1 | c.3754G>A p.V1252I (on ENST00000394104; = p.V1261I on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as COSV52922324; called by muse, mutect2, varscan2
- GOLGA4 | c.5940A>G p.K1980= | Splice Region (SNP) | VAF 10/181 reads (6%) | catalogued as COSV62710323; called by muse, mutect2
- HDAC9 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 6/101 reads (6%) | catalogued as COSV67771407; called by muse, mutect2
- HLA-B | c.701del p.P234Lfs*6 | Frame Shift Del (DEL) | VAF 40/129 reads (31%) | catalogued as rs753711860; called by pindel, varscan2
- ICAM5 | c.1123A>G p.N375D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs776404071, COSV55746928; called by muse, mutect2, varscan2
- INSYN1 | c.839T>A p.L280Q | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65837335; called by muse, mutect2, varscan2
- LAG3 | c.1088C>G p.S363C | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV52566934, COSV52567168; called by muse, mutect2, varscan2
- MASP1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 44/208 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV51459078; called by muse, mutect2
- MDN1 | c.8318A>T p.E2773V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV65520504; called by muse, mutect2, varscan2
- MTRR | c.1207A>G p.I403V (on ENST00000264668; = p.I376V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV52942868; called by muse, mutect2
- MYBBP1A | c.3014A>G p.H1005R | Missense Mutation (SNP) | VAF 108/175 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.327); catalogued as rs779629446, COSV54596706; called by muse, mutect2, varscan2
- NCAM1 | c.1640G>T p.W547L (on ENST00000316851 / NM_181351.5; = p.W537L on NM_000615.7) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV57514492; called by muse, mutect2, varscan2
- NCK2 | c.664A>G p.M222V | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV51890646; called by muse, mutect2, varscan2
- PELI1 | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV62729570, COSV62729888; called by muse, mutect2, varscan2
- PRB4 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 219/512 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.948); catalogued as COSV54396301, COSV54396460; called by muse, mutect2, varscan2
- PTPRJ | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.068); catalogued as COSV69251577; called by muse, mutect2, varscan2
- RFX5 | c.1846C>A p.P616T | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV51838667; called by muse, mutect2, varscan2
- ROMO1 | c.211A>G p.M71V | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs758659230, COSV53614931; called by muse, mutect2, varscan2
- RSPH3 | c.1252G>A p.D418N (on ENST00000252655; = p.D276N on NM_031924.8) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.065); catalogued as COSV51922061; called by muse, mutect2, varscan2
- SIPA1L2 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs371322486; called by muse, mutect2, varscan2
- SORBS2 | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.084); catalogued as COSV52997217; called by muse, mutect2, varscan2
- TENT5A | c.204G>T p.W68C | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60787819; called by muse, mutect2, varscan2
- TMCC3 | c.188A>T p.K63M | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54153688; called by muse, mutect2, varscan2
- UGDH | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as rs769243823, COSV57097233; called by muse, mutect2, varscan2
- USH2A | c.9201T>A p.N3067K | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56357629; called by muse, mutect2, varscan2
- AP1G1 | c.2346dup p.K783* | Frame Shift Ins (INS) | VAF 319/661 reads (48%) | called by mutect2, pindel, varscan2
- EPHB4 | c.2422_2442del p.I808_M814del | In Frame Del (DEL) | VAF 28/199 reads (14%) | called by mutect2, pindel
- PCARE | c.32dup p.N12Kfs*26 | Frame Shift Ins (INS) | VAF 44/100 reads (44%) | called by mutect2, pindel, varscan2
- PUS3 | c.258_274del p.N86Kfs*4 | Frame Shift Del (DEL) | VAF 75/204 reads (37%) | called by mutect2, pindel, varscan2
- RAD18 | c.890-3_890-2dup p.X297_splice | Splice Site (INS) | VAF 12/20 reads (60%) | called by mutect2, pindel, varscan2
- SENP8 | c.265del p.A89Pfs*44 | Frame Shift Del (DEL) | VAF 46/121 reads (38%) | called by mutect2, pindel, varscan2
- SMCHD1 | c.329del p.A110Vfs*39 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.940G>T p.G314W | Missense Mutation (SNP) | VAF 93/118 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM14 | c.344del p.F115Sfs*44 | Frame Shift Del (DEL) | VAF 46/118 reads (39%) | called by mutect2, pindel, varscan2
- WDR41 | c.185_199delinsTT p.D62Vfs*13 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by pindel, varscan2*
- ZZEF1 | c.7355del p.K2452Sfs*17 | Frame Shift Del (DEL) | VAF 97/368 reads (26%) | called by mutect2, pindel, varscan2
- C1orf194 | c.222C>T p.F74= (on ENST00000369948 / NM_001245025.3; = p.F62= on NM_001122961.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 88/199 reads (44%) | catalogued as COSV64049834; called by muse, mutect2, varscan2
- DENND4A | c.741T>C p.N247= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as COSV71265619; called by muse, mutect2, varscan2
- ECHDC1 | c.543A>G p.R181= (on ENST00000531967 / NM_001139510.1; = p.R175= on NM_001002030.2) | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV58932229; called by muse, mutect2, varscan2
- FNBP4 | c.2379T>C p.A793= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV55447920; called by muse, mutect2
- IQSEC1 | c.2190G>A p.V730= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs1222458877, COSV56223245; called by muse, mutect2, varscan2
- MYH2 | c.2703C>T p.A901= | Silent (SNP) | VAF 81/244 reads (33%) | catalogued as rs747870125, COSV55435864; called by muse, mutect2, varscan2
- RUSC2 | c.4230G>A p.L1410= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs1040929586, COSV63428376; called by muse, mutect2, varscan2
- TMTC2 | c.1188G>A p.L396= | Silent (SNP) | VAF 89/190 reads (47%) | catalogued as COSV58265943; called by muse, mutect2, varscan2
- WDR81 | c.3705G>A p.K1235= (on ENST00000409644 / NM_001163809.2; = p.K184= on NM_152348.4) | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs759967416, COSV58481101; called by muse, mutect2, varscan2
